Somatic mutation profile of tumor specimen TCGA-DX-A3UF-01A (aliquot TCGA-DX-A3UF-01A-11D-A307-09) from TCGA case TCGA-DX-A3UF, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 65.7 years (23,993 days).
Specimen TCGA-DX-A3UF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77e61c62-fcd4-4b1c-b3ab-882957c97b76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3UF-10A (Blood Derived Normal), aliquot TCGA-DX-A3UF-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7bea58b-55aa-462f-a95b-671b6bcd9b3d

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, RNA 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.658T>G p.Y220D | Missense Mutation (SNP) | VAF 45/57 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs530941076, COSV52691656, COSV52700454, COSV52760651, COSV53630086; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM22 | c.2264T>C p.I755T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV99715716; called by muse, mutect2, varscan2
- ADAMTSL2 | c.224T>A p.L75Q | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100618888; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4283C>T p.A1428V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99782036; called by muse, mutect2, varscan2
- ARHGAP32 | c.3185C>T p.P1062L (on ENST00000310343 / NM_001378025.1; = p.P713L on NM_014715.4) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100086857; called by muse, mutect2
- ASTN1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs866568425, COSV99920448, COSV99922367; called by muse, mutect2, varscan2
- CKAP2L | c.1175G>T p.S392I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); catalogued as COSV100198441; called by muse, mutect2
- CLDN15 | c.380C>G p.A127G | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.075); catalogued as COSV100385180; called by muse, mutect2, varscan2
- FBN1 | c.3210C>T p.D1070= | Splice Region (SNP) | VAF 23/56 reads (41%) | catalogued as rs754970748, COSV100353997; ClinVar: likely benign; called by muse, mutect2, varscan2
- FDPS | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV100756075; called by muse, mutect2, varscan2
- FGFR1 | c.496C>T p.H166Y (on ENST00000447712 / NM_023110.3; = p.H164Y on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.678); catalogued as rs772054562, COSV100247402; called by muse, mutect2, varscan2
- FOXO4 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV58575542; called by muse, mutect2, varscan2
- IARS1 | c.2348A>G p.N783S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as COSV100986775; called by muse, mutect2, varscan2
- IL20RA | c.514A>C p.M172L | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.07); catalogued as COSV100359799, COSV57358325; called by muse, mutect2
- ING2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV56563820, COSV56564497; called by muse, mutect2, varscan2
- KDM3A | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.172); catalogued as COSV100459980; called by muse, mutect2, varscan2
- KNTC1 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1452597981, COSV100337923; called by muse, mutect2, varscan2
- KSR2 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV100346913; called by muse, mutect2, varscan2
- LRRC40 | c.1724A>G p.N575S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100918699; called by muse, mutect2, varscan2
- MAGED1 | c.1115T>A p.L372Q | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); catalogued as COSV100431375; called by muse, mutect2, varscan2
- NPAP1 | c.1750T>C p.S584P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100274766; called by muse, mutect2, varscan2
- NPDC1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs557720412, COSV100063812; called by muse, mutect2, varscan2
- OR2T33 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs71642437, COSV100531574, COSV58814759; called by muse, mutect2, varscan2
- OR2T4 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100822393; called by muse, mutect2, varscan2
- OR7A5 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 49/110 reads (45%) | catalogued as COSV100457628; called by muse, mutect2, varscan2
- OXSM | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV99771910; called by muse, mutect2, varscan2
- PACS2 | c.1428G>T p.Q476H | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV100330595; called by muse, mutect2, varscan2
- PFKP | c.618G>C p.Q206H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.916); catalogued as COSV101126885; called by muse, mutect2, varscan2
- PKHD1L1 | c.1060C>A p.R354S | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as rs374182485, COSV101005352, COSV65744380; called by muse, mutect2, varscan2
- SLC22A14 | c.967T>C p.W323R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99828083; called by muse, mutect2, varscan2
- SYT1 | c.613C>G p.P205A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54039227, COSV99693692; called by muse, mutect2
- TECPR2 | c.1369G>C p.V457L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV100849816; called by muse, mutect2, varscan2
- TLR9 | c.2554G>A p.A852T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV100645550; called by muse, mutect2, varscan2
- ZW10 | c.1364A>T p.Y455F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99562442; called by muse, mutect2
- PPP6R1 | c.774_775dup p.E259Gfs*16 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- BMS1 | c.1080C>T p.H360= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as rs1194605534, COSV100996456; ClinVar: likely benign; called by muse, mutect2
- CHTOP | c.417C>T p.L139= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100904612; called by muse, mutect2, varscan2
- EMX1 | c.789G>A p.K263= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV50689690; called by muse, mutect2, varscan2
- GLIS1 | c.654G>A p.K218= | Silent (SNP) | VAF 29/43 reads (67%) | catalogued as COSV56547236; called by muse, mutect2, varscan2
- GLIS3 | c.2049C>T p.Y683= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100173266; called by muse, mutect2, varscan2
- GTPBP4 | c.1812G>C p.G604= | Silent (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- MYOM2 | c.2223C>A p.P741= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100036618; called by muse, mutect2, varscan2
- OR10Z1 | c.936A>G p.K312= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100778938, COSV100779023; called by muse, mutect2, varscan2
- PRR12 | c.846G>A p.A282= (on ENST00000615927; = p.A1103= on NM_020719.3) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1210149743, COSV101330554, COSV101330783; called by muse, mutect2
- SLC2A6 | c.606G>A p.A202= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs782128064, COSV52469550, COSV99390084; called by muse, mutect2, varscan2
- TRIM42 | c.693C>A p.R231= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV99647963; called by muse, mutect2
- OR52A4P | n.659T>G | RNA (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
